Somatic mutation profile of tumor specimen MBCProject_0105_T2_WES (aliquot MBCProject_0105_T2_WES_1) from CMI case MBCProject_0105, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 39.3 years (14,367 days).
Specimen MBCProject_0105_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0ad030c-034a-4315-a8a8-fa5be7feaac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0105_SALIVA (Saliva), aliquot MBCProject_0105_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dacac5de-8ba5-40a1-b464-f6c9299ebade

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPS8 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs942668478; called by muse, mutect2
- GTF2E1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs777114113, COSV52203198; called by mutect2, varscan2
- UNC13D | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as rs761043074, COSV104368800; ClinVar: uncertain significance; called by mutect2, varscan2
- DCAF11 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, varscan2
- GTF2H4 | c.787del p.Q263Nfs*84 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- BCL2L14 | c.625C>T p.L209= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- EFCAB12 | c.381G>A p.E127= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, varscan2
- CRACR2B | c.*20G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58989026; called by muse, varscan2
- MMADHC | c.610-1104T>C | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1323302195; called by mutect2, varscan2
